Somatic mutation profile of tumor specimen TARGET-20-PASKAS-09A (aliquot TARGET-20-PASKAS-09A-01D) from TARGET case TARGET-20-PASKAS, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.0 years (367 days).
Specimen TARGET-20-PASKAS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66cdf1f0-9836-4a2c-93c0-f72d500fa230.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASKAS-14A (Bone Marrow Normal), aliquot TARGET-20-PASKAS-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d57b3a3-f118-469a-b0bf-0533f860e1e9

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Frame Shift Del 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL2 | c.1767_1769delinsT p.E589Dfs*18 | Frame Shift Del (DEL) | VAF 33/162 reads (20%) | called by pindel, varscan2*
- KMT5B | c.230T>C p.L77P | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
